Gene-level copy-number profile of tumor specimen TCGA-VQ-A91A-01A from TCGA case TCGA-VQ-A91A, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIB; Tumor grade: G1; Age at diagnosis: 67.5 years (24,670 days).
Specimen TCGA-VQ-A91A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.794ad486-38e0-45bf-b8b6-105300bede85.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VQ-A91A-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/430b7d1c-8ab1-487e-b0e6-7b93ef681583

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 1,239; copy number 2: 24,620; copy number 3: 21,147; copy number 4: 9,013; copy number 5: 2,318; copy number 6: 1,033; copy number 7: 79; copy number 8: 84; copy number 9: 48; copy number 10: 83; copy number 11: 149.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VQ-A91A-01A-11D-A40Z-01): tumor purity 0.39, ploidy 2.97, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:4,963,954–4,981,568, 2 genes: BX005132.1, LINC02781.
- chr16:78,525,189–78,553,296, 3 genes: AC046158.4, AC046158.2, AC046158.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,794 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:196,850,283–205,469,024, 220 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr3:157,436,850–163,361,563, 74 genes, copy number 5 (broad region; genes not listed).
- chr5:58,198–50,603,511, 712 genes, copy number 6–7 (broad region; genes not listed).
- chr5:57,574,027–58,161,752, 7 genes, copy number 5: LINCR-0003, AC008780.1, AC106822.1, LINC02225, LINC02101, AC008786.1, PGAM1P1.
- chr5:109,165,289–111,997,464, 36 genes, copy number 5 (within-gene range 2–5): AC116428.1, AC008467.1, PJA2, AC010625.1, AC091917.3, AC091917.2, AC091917.1, KRT18P42, MAN2A1-DT, MAN2A1, RN7SKP230, AC008417.1, LINC01848, PGAM5P1, TMEM232, MIR548F3, AC008650.1, SLC25A46, AC008782.1, BCLAF1P1, AC010395.1, AC010395.2, TSLP, AC008572.1, WDR36, AC010468.2, RPS3AP21, CAMK4, AC010468.1, AC010275.1, STARD4, STARD4-AS1, HMGN1P13, AC008967.1, NREP, RN7SKP57.
- chr8:93,698,561–104,589,024, 247 genes, copy number 5–6 (broad region; genes not listed).
- chr8:104,699,479–104,703,555, 1 gene, copy number 5: AC012564.1.
- chr8:106,697,427–109,691,791, 33 genes, copy number 5 (within-gene range 4–5): TAGLN2P1, RNU7-84P, ABRA, AP003789.1, AP000428.2, HMGB1P46, AP000428.1, ANGPT1, AC091010.1, PGAM1P13, AC025508.1, RNA5SP275, RSPO2, NRBF2P4, AURKBP1, EIF3E, AC087620.1, RPS17P14, EMC2, AC022634.1, AC022634.2, TMEM74, TRMT10BP1, AC104248.1, TRHR, NUDCD1, AC021237.1, ENY2, PKHD1L1, MAPK6P5, EBAG9, SYBU, AC079061.1.
- chr8:112,222,928–113,436,939, 1 gene, copy number 5 (within-gene range 4–5): CSMD3.
- chr8:112,538,889–119,325,265, 44 genes, copy number 5: RPL30P16, MIR2053, AC107890.1, AC055788.2, AC055788.1, AC103993.1, Y_RNA, AC064802.1, AC025881.1, CARS1P2, TRPS1, AF178030.1, LINC00536, RNA5SP276, AC090994.1, AC105177.1, EIF3H, UTP23, RAD21, RAD21-AS1, MIR3610, AARD, SLC30A8, RN7SL228P, AC027419.1, AC027419.2, RN7SL826P, AC084114.1, AP002848.1, MED30, RPS10P16, EXT1, SAMD12, AC023590.1, SAMD12-AS1, RPS26P35, TNFRSF11B, RNU6-12P, AC107953.1, COLEC10, AC107953.2, MAL2, MAL2-AS1, MIR548AZ.
- chr8:119,711,830–125,438,403, 104 genes, copy number 5 (broad region; genes not listed).
- chr8:126,556,323–127,419,050, 1 gene, copy number 5 (within-gene range 4–5): PCAT1.
- chr8:126,766,196–138,497,261, 129 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr10:14,877,688–32,882,874, 306 genes, copy number 5–10 (broad region; genes not listed).
- chr10:33,341,655–42,834,937, 124 genes, copy number 6 (broad region; genes not listed).
- chr10:72,560,264–81,875,133, 219 genes, copy number 8–11 (broad region; genes not listed).
- chr11:66,744,451–83,134,737, 459 genes, copy number 5 (broad region; genes not listed).
- chr16:5,239,802–7,713,340, 1 gene, copy number 6 (within-gene range 2–6): RBFOX1.
- chr16:6,573,767–8,376,276, 16 genes, copy number 6: AC007223.1, AC007012.2, AC007012.1, RNU7-99P, RNU6-457P, RNU6-328P, AC022206.1, AC007222.2, AC007222.1, AC005774.2, AC005774.1, AC093515.1, AC018767.2, LINC02152, AC018767.3, AC018767.1.
- chr17:61,865,367–68,797,822, 214 genes, copy number 5 (broad region; genes not listed).
- chr17:70,628,917–70,779,230, 2 genes, copy number 5: AC005771.1, AC007423.1.
- chr19:22,286,441–28,313,500, 103 genes, copy number 6–9 (within-gene range 3–9) (broad region; genes not listed).
- chr20:30,484,925–60,653,784, 741 genes, copy number 5–7 (within-gene range 2–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,239. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
